Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A5SL, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A5SL-01A (Primary Tumor).

[page 1 of 2]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the
the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try print

DOB

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status Final

Ordering Provider

Relevant

Information

Location

Report Patient

Demographics

(for verification
purposes)

Date of Birth:

Sex: M

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver, hepatic NOS
C22.0

Jan 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description
A: Gallbladder
B: Right lobe of liver

Clinical Information
Alcoholic liver tumor
Infectious patient: No
Immunocompromised: No
History of neoplasm: yes

Diagnosis

A: Gallbladder:
Within Normal Limits

B: Right lobe of liver:
Moderately Differentiated Hepatocellular Carcinoma (5.5 cm)
With Lymphovascular Invasion
Tumor 0.15 cm away from inked margin.

Nonneoplastic liver contains numerous noncaseating sarcoid like
granulomas. Sarcoid like reactions may be seen in response to tumor.

No definite histologic features present to suggest chronic alcohol related
disease.

[page 2 of 2]
Electronically signed by:
Verified

Gross Description

Received are specimens A and B. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and AP identifiers are labelled with the Surgical Number

A: The specimen consists of an intact gallbladder which measures 9.5 x 5 x 3 cm. Cystic duct lymph node is not identified with the specimen. Approximately 30 cc of bile are present within the gallbladder. No gallstones are identified. No masses or polyps are

noted on the mucosal surface. A few yellowish flecks are noted on the mucosal surface. The gallbladder wall measures 0.2 cm in maximum dimension. The gallbladder is grossly within normal limits. Representative sections of the cystic duct, body, and fundus are submitted in A1.

B: The specimen consists of a lobe of liver which weighs 671 g and measures 23 x 14 x 9 cm. Surgical resection margin has been painted with blue ink. Within the liver, there is a circumscribed greenish tinged nodule which measures 5.5 cm in maximum dimension. It is located to within 1 mm of the inked surgical margin, but does not appear to touch the inked margin. No other masses or nodules are noted within the liver. The surrounding liver parenchyma is slightly yellow and looks like it might have some areas of possible congestion. No other abnormalities are noted. Section submitted for tumor bank and representative sections taken as follows:

A1: Section of non neoplastic liver
A2: Section of liver tumor and nearest margin
A3: Section of liver tumor and adjacent normal liver

Accession
Number
Enclosure
Number
Page

- END OF PRINTED REPORT -

Specimen Discrepancy		✓
Other Discrepancy		✓
Diagnosis/Procedure Primary Noted		

Source: NCI Genomic Data Commons file 3d6f7954-6bdd-45e0-807a-62ad63c6b282 (TCGA-G3-A5SL.7DB1AFB2-69C9-4277-904E-4CF9CBAE8360.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).